Somatic mutation profile of tumor specimen TARGET-30-PASAFG-01A (aliquot TARGET-30-PASAFG-01A-01D) from TARGET case TARGET-30-PASAFG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.3 years (2,305 days).
Specimen TARGET-30-PASAFG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c9b6d75-7cb2-4ec9-be32-6c76f49abf05.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASAFG-10A (Blood Derived Normal), aliquot TARGET-30-PASAFG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9a743c0-17b6-42c2-8af9-1a577269f179

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF814 | c.2105A>T p.H702L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as COSV71382334; called by muse, mutect2, varscan2
- DNAH2 | c.2256C>A p.G752= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
